Somatic mutation profile of tumor specimen TCGA-EM-A1CT-01A (aliquot TCGA-EM-A1CT-01A-11D-A13W-08) from TCGA case TCGA-EM-A1CT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 76.5 years (27,944 days).
Specimen TCGA-EM-A1CT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d5294fc-2162-4e3b-b03c-dbb37a5777b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1CT-10A (Blood Derived Normal), aliquot TCGA-EM-A1CT-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/133a3585-4e76-4ac9-ae98-08e88648414b

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 11, Silent 9, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DBT | c.704T>C p.M235T | Missense Mutation (SNP) | VAF 125/318 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV64496413; called by muse, mutect2, varscan2
- DENND4B | c.3206G>A p.R1069H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs780951206, COSV63412304; called by muse, mutect2, varscan2
- GPNMB | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.506); catalogued as COSV51701395; called by muse, mutect2
- H2BC5 | c.274T>C p.S92P | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV56803803; called by muse, mutect2, varscan2
- HMCN1 | c.4003G>C p.E1335Q | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.683); catalogued as COSV54945800; called by muse, mutect2, varscan2
- HNRNPCL1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs199978302; called by muse, mutect2, varscan2
- MPHOSPH8 | c.739A>T p.K247* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV64057975; called by muse, mutect2, varscan2
- PIK3CG | c.1413C>A p.H471Q | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV63254387; called by muse, mutect2, varscan2
- SZT2 | c.871T>G p.F291V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV68812563; called by muse, mutect2, varscan2
- VSIG2 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52519632; called by muse, mutect2, varscan2
- ZFAND1 | c.785A>T p.N262I | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV55108844; called by muse, mutect2, varscan2
- ATM | c.5723del p.T1908Kfs*9 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- CCDC39 | c.2583A>G p.Q861= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV56494801; called by muse, mutect2, varscan2
- CEP290 | c.1305G>A p.R435= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV58356998; called by muse, mutect2, varscan2
- DNASE1L3 | c.18C>G p.A6= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV59157604; called by muse, mutect2
- DOCK4 | c.2671T>C p.L891= | Silent (SNP) | VAF 9/205 reads (4%) | catalogued as rs1326975792, COSV70243960; called by muse, mutect2
- MTMR8 | c.1827C>T p.H609= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- NALCN | c.3672G>A p.S1224= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs760958889, COSV51933866; called by muse, mutect2, varscan2
- TBC1D25 | c.318C>A p.L106= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV65124750; called by muse, mutect2
- TEX15 | c.7776G>A p.V2592= (on ENST00000256246; = p.V2975= on NM_001350162.2) | Silent (SNP) | VAF 61/163 reads (37%) | catalogued as COSV56354985; called by muse, mutect2, varscan2
- TMPO | c.1392T>C p.V464= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV54125474; called by muse, mutect2, varscan2
